Somatic mutation profile of tumor specimen C3N-03223-02 (aliquot CPT0191400009) from CPTAC case C3N-03223, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 54.2 years (19,793 days).
Specimen C3N-03223-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60c1bf7b-2747-46ed-abab-22a2d589ec9c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03223-71 (Blood Derived Normal), aliquot CPT0191510002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/266fe0f4-b648-4642-be52-0e84bcc9dca3

The open-access MAF lists 299 somatic variants for this specimen: 206 protein-altering or splice-affecting, 79 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 186, Silent 79, Intron 9, Nonsense Mutation 7, Frame Shift Del 5, Splice Region 4, 5'UTR 2, Splice Site 2, 3'UTR 1, In Frame Del 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 129/285 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACSM1 | c.1146G>A p.M382I | Missense Mutation (SNP) | VAF 149/338 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV54633076; called by muse, mutect2, varscan2
- ADAM23 | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 174/375 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.125); catalogued as rs758501499, COSV100008282; called by muse, mutect2, varscan2
- AGR3 | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 103/246 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV100124020; called by muse, mutect2, varscan2
- ALKBH4 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 160/385 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV52962156; called by muse, mutect2, varscan2
- ANGPT4 | c.1243G>A p.G415S | Missense Mutation (SNP) | VAF 126/288 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as rs760416354; called by muse, mutect2, varscan2
- ANKRD62 | c.2287G>A p.E763K | Missense Mutation (SNP) | VAF 171/379 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as COSV58413304; called by muse, mutect2, varscan2
- ARNT | c.2098C>T p.R700C | Missense Mutation (SNP) | VAF 142/303 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs754824680, COSV100591328; called by muse, mutect2, varscan2
- ATP7B | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 19/650 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV54440395; called by muse, mutect2
- BRINP1 | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 230/465 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1564218903; called by muse, mutect2, varscan2
- CCDC112 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 129/343 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.134); catalogued as COSV65473675; called by muse, mutect2, varscan2
- CCDC83 | c.1229A>T p.K410M (on ENST00000342404 / NM_001286159.2; = p.K441M on NM_173556.5) | Missense Mutation (SNP) | VAF 112/264 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54699743; called by muse, mutect2, varscan2
- CD79A | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 99/235 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as rs1355355628, COSV55739817; called by muse, mutect2, varscan2
- CELA3B | c.563G>C p.C188S | Missense Mutation (SNP) | VAF 144/487 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61404234, COSV61404577; called by muse, mutect2, varscan2
- CNTNAP3 | c.2929G>A p.E977K | Missense Mutation (SNP) | VAF 183/516 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1171155057; called by muse, mutect2, varscan2
- COL27A1 | c.3727G>A p.G1243R | Missense Mutation (SNP) | VAF 215/240 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61921631; called by muse, mutect2, varscan2
- COL2A1 | c.2129C>T p.P710L | Missense Mutation (SNP) | VAF 172/496 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as rs747446924; called by muse, mutect2, varscan2
- CPNE8 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as rs1477405796; called by muse, mutect2, varscan2
- CRB1 | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 161/357 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as COSV66330452; called by muse, mutect2, varscan2
- CYP2E1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 123/140 reads (88%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV99429278; called by muse, mutect2, varscan2
- DDX60L | c.4261G>A p.G1421R | Missense Mutation (SNP) | VAF 165/359 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs1300275652; called by muse, mutect2, varscan2
- DIAPH1 | c.491G>A p.C164Y | Missense Mutation (SNP) | VAF 158/183 reads (86%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV53883554; called by muse, mutect2, varscan2
- ELMO2 | c.1393G>T p.A465S | Missense Mutation (SNP) | VAF 127/281 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV51682335; called by mutect2, varscan2
- FAM71E2 | c.812A>G p.E271G | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1367993843; called by muse, mutect2
- GBP7 | c.658C>G p.P220A | Missense Mutation (SNP) | VAF 13/363 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as COSV99643550; called by muse, mutect2
- GPR137 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 188/449 reads (42%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV57402808; called by muse, mutect2, varscan2
- GPR158 | c.3128C>T p.S1043F | Missense Mutation (SNP) | VAF 137/304 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1374104989, COSV66264976, COSV66273219; called by muse, mutect2, varscan2
- GRM1 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 154/181 reads (85%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as COSV51170722, COSV51187241; called by muse, mutect2, varscan2
- HDAC9 | c.3062G>A p.R1021K (on ENST00000441542 / NM_178425.3; = p.R1018K on NM_178423.3) | Missense Mutation (SNP) | VAF 154/385 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs529908311; called by muse, mutect2, varscan2
- HELB | c.2836C>T p.R946C | Missense Mutation (SNP) | VAF 208/439 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs774433175, COSV56072110; called by muse, mutect2, varscan2
- HJV | c.391C>T p.R131W (on ENST00000336751 / NM_213653.4; = p.R18W on NM_145277.5) | Missense Mutation (SNP) | VAF 26/836 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs782353082; called by muse, mutect2
- ICAM5 | c.2357G>A p.G786E | Missense Mutation (SNP) | VAF 56/769 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV55749615; called by muse, mutect2
- KITLG | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 103/125 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99933485; called by muse, mutect2, varscan2
- LRIT3 | c.366G>A p.W122* | Nonsense Mutation (SNP) | VAF 149/329 reads (45%) | catalogued as COSV100016130; called by muse, mutect2, varscan2
- LRP1B | c.12544G>A p.E4182K | Missense Mutation (SNP) | VAF 130/292 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs201840295, COSV101254959; called by muse, mutect2, varscan2
- LUZP1 | c.2732G>A p.G911D | Missense Mutation (SNP) | VAF 26/452 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.295); catalogued as COSV56500588; called by muse, mutect2
- MECOM | c.451C>T p.R151C (on ENST00000468789 / NM_001105078.4; = p.R339C on NM_004991.4) | Missense Mutation (SNP) | VAF 171/384 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs981426353; called by muse, mutect2, varscan2
- MYT1 | c.2247G>T p.E749D | Missense Mutation (SNP) | VAF 126/379 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.07); catalogued as COSV60510946; called by muse, mutect2, varscan2
- NDST4 | c.2533C>T p.H845Y | Missense Mutation (SNP) | VAF 268/285 reads (94%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as COSV52121706; called by muse, mutect2, varscan2
- NEK10 | c.1927C>T p.R643* | Nonsense Mutation (SNP) | VAF 159/328 reads (48%) | catalogued as rs776635841, COSV58281225; called by muse, mutect2, varscan2
- NIPSNAP1 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 183/433 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV53343121; called by muse, mutect2, varscan2
- NONO | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 205/268 reads (76%) | SIFT deleterious (0.05); PolyPhen benign (0.364); catalogued as COSV52137317, COSV52141002; called by muse, varscan2
- NPC1L1 | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 178/370 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.185); catalogued as COSV56924838; called by muse, mutect2, varscan2
- OR10K1 | c.240G>C p.K80N | Missense Mutation (SNP) | VAF 176/380 reads (46%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV56871991; called by muse, mutect2, varscan2
- OR2T33 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 205/638 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58815795; called by muse, varscan2
- OR2Z1 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 198/472 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs558277343, COSV100136504; called by muse, mutect2
- OR5F1 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 160/369 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs781270833; called by muse, mutect2, varscan2
- OR6C1 | c.315G>T p.L105F | Missense Mutation (SNP) | VAF 107/278 reads (38%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.033); catalogued as COSV65574224; called by muse, mutect2, varscan2
- OR8G5 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 27/593 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs769313524, COSV100422529; called by muse, mutect2
- PAPPA2 | c.1921G>A p.D641N | Missense Mutation (SNP) | VAF 182/419 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.068); catalogued as rs757471049, COSV62785060; called by muse, mutect2, varscan2
- PLCB4 | c.3007C>T p.Q1003* | Nonsense Mutation (SNP) | VAF 217/238 reads (91%) | catalogued as COSV53819426; called by muse, mutect2, varscan2
- PLCH1 | c.2773C>T p.P925S (on ENST00000340059 / NM_001130960.2; = p.P917S on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 170/423 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100396251; called by muse, mutect2, varscan2
- PRAMEF4 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 178/526 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99340259; called by muse, mutect2, varscan2
- PRKAR1A | c.154del p.E52Nfs*77 | Frame Shift Del (DEL) | VAF 93/157 reads (59%) | catalogued as COSV100675218; called by mutect2, pindel, varscan2
- PRSS37 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 99/226 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs766210306, COSV63339047; called by muse, mutect2, varscan2
- RP1 | c.4261G>A p.E1421K | Missense Mutation (SNP) | VAF 141/320 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55116321; called by muse, mutect2, varscan2
- RP1L1 | c.2516G>A p.R839Q | Missense Mutation (SNP) | VAF 241/296 reads (81%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375534027; ClinVar: benign; called by muse, mutect2, varscan2
- RPF1 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 86/213 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.534); catalogued as rs138714678; called by muse, mutect2, varscan2
- RSPO4 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 27/506 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.563); catalogued as COSV54082821; called by muse, mutect2
- RUSC2 | c.4315C>T p.P1439S | Missense Mutation (SNP) | VAF 203/471 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1249338803; called by muse, mutect2, varscan2
- SALL2 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 186/479 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145077959; called by muse, mutect2, varscan2
- SHROOM4 | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 295/336 reads (88%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1364010031; called by muse, mutect2, varscan2
- SLC22A25 | c.1394G>A p.R465K | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs867131694; called by muse, mutect2, varscan2
- SNCAIP | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 171/400 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs901682731, COSV54408079; called by muse, mutect2, varscan2
- SPNS3 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 162/208 reads (78%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.932); catalogued as COSV61069700; called by muse, mutect2, varscan2
- SRC | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 389/424 reads (92%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1406655378, COSV100658096; called by muse, mutect2, varscan2
- SYNE1 | c.337G>A p.D113N (on ENST00000367255 / NM_182961.4; = p.D120N on NM_033071.3) | Missense Mutation (SNP) | VAF 152/186 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs990137456, COSV55003846; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF1L | c.3614G>A p.R1205Q | Missense Mutation (SNP) | VAF 237/284 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs749284231, COSV54256396; called by muse, mutect2, varscan2
- TAF5L | c.1163G>T p.W388L | Missense Mutation (SNP) | VAF 26/500 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51085450; called by muse, mutect2
- TERT | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 228/554 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1304418053, COSV57245436; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TEX13B | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 327/377 reads (87%) | SIFT tolerated (0.26); PolyPhen benign (0.095); catalogued as rs750553934; called by muse, mutect2, varscan2
- TIMM50 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 110/292 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); catalogued as rs867512466; called by muse, varscan2
- TMPRSS13 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 123/277 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as rs755250130; called by muse, mutect2, varscan2
- TRAV3 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 115/264 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as rs375744366; called by muse, mutect2, varscan2
- TRPC7 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 221/256 reads (86%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs1349878126, COSV61453027; called by muse, mutect2, varscan2
- UBD | c.186C>A p.S62R | Missense Mutation (SNP) | VAF 281/618 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1462409167; called by muse, mutect2, varscan2
- URB2 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 263/545 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs140253441; called by muse, mutect2, varscan2
- ZNF530 | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 241/511 reads (47%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.965); catalogued as COSV60532218; called by muse, mutect2, varscan2
- ACAN | c.6967A>T p.S2323C | Missense Mutation (SNP) | VAF 85/244 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by mutect2, varscan2
- ACKR2 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 154/377 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- AGRN | c.5982G>A p.G1994= | Splice Region (SNP) | VAF 159/375 reads (42%) | called by muse, mutect2
- AIFM3 | c.1525A>G p.T509A | Missense Mutation (SNP) | VAF 26/582 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.07); called by muse, mutect2
- AL138999.2 | n.841A>C | Splice Region (SNP) | VAF 233/380 reads (61%) | called by muse, mutect2, varscan2
- ALS2CL | c.913G>T p.A305S | Missense Mutation (SNP) | VAF 74/400 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ARHGAP31 | c.2890C>A p.Q964K | Missense Mutation (SNP) | VAF 213/476 reads (45%) | SIFT tolerated (0.81); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ARHGEF37 | c.1616A>T p.K539M | Missense Mutation (SNP) | VAF 21/248 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.266); called by muse, mutect2
- ATG2B | c.2048A>G p.E683G | Missense Mutation (SNP) | VAF 24/424 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ATP2B1 | c.917del p.K306Rfs*31 | Frame Shift Del (DEL) | VAF 13/97 reads (13%) | called by mutect2, pindel, varscan2
- ATP6V0A4 | c.818T>G p.V273G | Missense Mutation (SNP) | VAF 108/229 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BARD1 | c.1569T>C p.V523= | Splice Region (SNP) | VAF 64/191 reads (34%) | called by muse, mutect2, varscan2
- BDH2 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 130/334 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- BMP2K | c.2936C>T p.S979F | Missense Mutation (SNP) | VAF 397/425 reads (93%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- C10orf71 | c.1717C>A p.Q573K | Missense Mutation (SNP) | VAF 168/202 reads (83%) | SIFT tolerated (0.08); PolyPhen benign (0.255); called by mutect2, varscan2
- C1S | c.1554A>T p.E518D | Missense Mutation (SNP) | VAF 18/481 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- C5AR1 | c.905T>C p.V302A | Missense Mutation (SNP) | VAF 28/524 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.155); called by muse, mutect2
- CACNA2D4 | c.1774T>C p.S592P | Missense Mutation (SNP) | VAF 133/411 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CCDC168 | c.10289G>A p.G3430E | Missense Mutation (SNP) | VAF 328/494 reads (66%) | SIFT tolerated (0.19); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CCDC81 | c.1943C>T p.S648F (on ENST00000445632 / NM_001156474.2; = p.S558F on NM_021827.4) | Missense Mutation (SNP) | VAF 185/362 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CELSR2 | c.8146C>T p.P2716S | Missense Mutation (SNP) | VAF 157/336 reads (47%) | SIFT tolerated (0.82); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CFAP44 | c.4867C>T p.L1623F | Missense Mutation (SNP) | VAF 107/272 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- CFTR | c.2630C>T p.S877F | Missense Mutation (SNP) | VAF 171/391 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CLASP2 | c.271del p.M91Wfs*4 | Frame Shift Del (DEL) | VAF 66/170 reads (39%) | called by mutect2, pindel*, varscan2
- CNGA4 | c.870G>A p.M290I | Missense Mutation (SNP) | VAF 172/400 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- COL4A2 | c.4121G>A p.G1374E | Missense Mutation (SNP) | VAF 152/513 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPAMD8 | c.3124G>A p.A1042T (on ENST00000651564; = p.A995T on NM_015692.5) | Missense Mutation (SNP) | VAF 286/657 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CPT1C | c.1037C>A p.T346N | Missense Mutation (SNP) | VAF 124/432 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- CT45A1 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 133/373 reads (36%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- CTRC | c.442C>A p.L148M | Missense Mutation (SNP) | VAF 41/524 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2
- CTRC | c.443T>A p.L148Q | Missense Mutation (SNP) | VAF 41/520 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.056); called by muse, mutect2
- CYP24A1 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 64/297 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DACH1 | c.1508G>A p.R503K (on ENST00000619232 / NM_001366712.1; = p.R451K on NM_080759.6) | Missense Mutation (SNP) | VAF 193/660 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- DNAH12 | c.814A>G p.T272A | Missense Mutation (SNP) | VAF 143/336 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- DNAH9 | c.12697A>G p.T4233A | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- DNAJC5G | c.343T>C p.Y115H | Missense Mutation (SNP) | VAF 111/265 reads (42%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- DOCK6 | c.3214C>T p.P1072S | Missense Mutation (SNP) | VAF 48/598 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.222); called by muse, mutect2
- DPP4 | c.1198G>A p.G400S | Missense Mutation (SNP) | VAF 101/220 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- DTL | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 162/382 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- EFHB | c.1624G>A p.D542N | Missense Mutation (SNP) | VAF 146/378 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- FAT4 | c.11114G>A p.G3705E | Missense Mutation (SNP) | VAF 358/384 reads (93%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FGFBP1 | c.338G>A p.W113* | Nonsense Mutation (SNP) | VAF 156/370 reads (42%) | called by muse, mutect2, varscan2
- FMN1 | c.3400A>G p.I1134V (on ENST00000616417 / NM_001277313.2; = p.I911V on NM_001103184.4) | Missense Mutation (SNP) | VAF 18/418 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2
- FOLH1 | c.554T>C p.F185S | Missense Mutation (SNP) | VAF 138/385 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAGE10 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 39/456 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.206); called by muse, varscan2
- GATAD2B | c.1064C>G p.A355G | Missense Mutation (SNP) | VAF 21/784 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2
- GIPC3 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 168/416 reads (40%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- GOLGA5 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 16/392 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRID1 | c.1898T>G p.V633G | Missense Mutation (SNP) | VAF 212/247 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRM1 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 157/182 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HEATR4 | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 160/367 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HMMR | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2
- HNF4G | c.567G>A p.M189I (on ENST00000354370 / NM_001330561.2; = p.M236I on NM_004133.5) | Missense Mutation (SNP) | VAF 108/272 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- IGHV3OR16-13 | c.96del p.Q32Hfs*6 | Frame Shift Del (DEL) | VAF 136/556 reads (24%) | called by pindel, varscan2
- IQGAP3 | c.2681A>G p.D894G | Missense Mutation (SNP) | VAF 141/366 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- IRAK2 | c.753A>T p.E251D | Missense Mutation (SNP) | VAF 18/462 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2
- IRAK2 | c.754A>T p.R252* | Nonsense Mutation (SNP) | VAF 18/464 reads (4%) | called by muse, mutect2
- JHY | c.1442C>T p.S481L | Missense Mutation (SNP) | VAF 190/409 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KIF21B | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 156/525 reads (30%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL34 | c.343C>A p.L115M | Missense Mutation (SNP) | VAF 288/335 reads (86%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- KRT75 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 223/514 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- LMNB1 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 209/461 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- LOXHD1 | c.4883C>T p.P1628L | Missense Mutation (SNP) | VAF 94/207 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP6 | c.917G>A p.R306K | Missense Mutation (SNP) | VAF 127/281 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MYOM3 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 166/344 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.057); called by muse, mutect2
- NCAN | c.1441G>A p.G481R | Missense Mutation (SNP) | VAF 63/645 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- NEB | c.9152C>A p.A3051D | Missense Mutation (SNP) | VAF 181/438 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NELFB | c.1041-1G>A p.X347_splice | Splice Site (SNP) | VAF 119/292 reads (41%) | called by muse, mutect2, varscan2
- NEURL1B | c.903_947del p.P302_P316del | In Frame Del (DEL) | VAF 175/439 reads (40%) | called by mutect2, pindel, varscan2
- NEXMIF | c.3143A>T p.E1048V | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NEXN | c.860A>G p.Q287R | Missense Mutation (SNP) | VAF 85/247 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NLRP4 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 167/390 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NOTCH3 | c.4762A>C p.N1588H | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- NTHL1 | c.103G>A p.E35K (on ENST00000219066; = p.E27K on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 229/510 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OCIAD2 | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 120/260 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- OSBPL10 | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 179/388 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- OSER1 | c.425A>G p.H142R | Missense Mutation (SNP) | VAF 26/442 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2
- PANK4 | c.1137G>T p.W379C | Missense Mutation (SNP) | VAF 21/525 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PCNX2 | c.4718T>C p.L1573P | Missense Mutation (SNP) | VAF 194/458 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PLEKHG4 | c.1438G>C p.A480P | Missense Mutation (SNP) | VAF 181/636 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXND1 | c.2446A>G p.T816A | Missense Mutation (SNP) | VAF 24/434 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- PLXND1 | c.1128G>T p.Q376H | Missense Mutation (SNP) | VAF 180/405 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by mutect2, varscan2
- PPFIBP1 | c.1514_1515insG p.G506Rfs*8 (on ENST00000318304 / NM_177444.3; = p.G489Rfs*8 on NM_003622.4) | Frame Shift Ins (INS) | VAF 117/423 reads (28%) | called by mutect2, pindel, varscan2
- PRAMEF17 | c.1063A>G p.T355A | Missense Mutation (SNP) | VAF 106/364 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PSAT1 | c.353T>C p.F118S | Missense Mutation (SNP) | VAF 185/416 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PTGER2 | c.605C>T p.T202I | Missense Mutation (SNP) | VAF 175/392 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PTK7 | c.894C>G p.I298M | Missense Mutation (SNP) | VAF 17/602 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.218); called by muse, mutect2
- PUS7L | c.1333A>G p.I445V | Missense Mutation (SNP) | VAF 129/247 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- RCSD1 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 160/413 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- RELN | c.5216C>T p.P1739L | Missense Mutation (SNP) | VAF 90/193 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RGMA | c.1048A>T p.T350S | Missense Mutation (SNP) | VAF 102/573 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RNF216 | c.1918T>A p.W640R (on ENST00000425013 / NM_207116.3; = p.W697R on NM_207111.4) | Missense Mutation (SNP) | VAF 126/247 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by mutect2, varscan2
- ROS1 | c.1672C>A p.P558T | Missense Mutation (SNP) | VAF 42/472 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RPS6KA2 | c.1369A>G p.I457V | Missense Mutation (SNP) | VAF 154/174 reads (89%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- S1PR4 | c.765G>A p.M255I | Missense Mutation (SNP) | VAF 261/623 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- SALL1 | c.1411C>T p.H471Y | Missense Mutation (SNP) | VAF 207/245 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SCTR | c.210G>A p.W70* | Nonsense Mutation (SNP) | VAF 33/426 reads (8%) | called by muse, mutect2
- SLC26A2 | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 121/143 reads (85%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SMG7 | c.328T>C p.C110R | Missense Mutation (SNP) | VAF 90/221 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMUG1 | c.98A>G p.E33G | Missense Mutation (SNP) | VAF 19/562 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2
- SOX11 | c.834C>G p.S278R | Missense Mutation (SNP) | VAF 32/536 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- STARD13 | c.590C>T p.S197F (on ENST00000336934 / NM_001243476.3; = p.S79F on NM_052851.3) | Missense Mutation (SNP) | VAF 233/698 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SUPT5H | c.1833A>C p.E611D | Missense Mutation (SNP) | VAF 39/265 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TH | c.650A>C p.D217A (on ENST00000381178 / NM_199292.3; = p.D186A on NM_000360.4) | Missense Mutation (SNP) | VAF 189/396 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- TIMM50 | c.961-1G>A p.X321_splice | Splice Site (SNP) | VAF 120/314 reads (38%) | called by muse, mutect2, varscan2
- TMDD1 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 30/456 reads (7%) | PolyPhen probably damaging (0.98); called by muse, mutect2
- TMEM192 | c.415C>T p.L139F | Missense Mutation (SNP) | VAF 143/355 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMPRSS11A | c.1033G>T p.V345L | Missense Mutation (SNP) | VAF 135/402 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.351); called by mutect2, varscan2
- TRABD2A | c.1445C>A p.A482D (on ENST00000409520 / NM_001277053.2; = p.A433D on NM_001080824.3) | Missense Mutation (SNP) | VAF 210/445 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); called by mutect2, varscan2
- TRAF4 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 253/289 reads (88%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- TREX1 | c.567del p.Q189Hfs*88 (on ENST00000625293 / NM_033629.6; = p.Q179Hfs*88 on NM_007248.5) | Frame Shift Del (DEL) | VAF 243/614 reads (40%) | called by mutect2, pindel, varscan2
- TRIM50 | c.1304A>G p.D435G | Missense Mutation (SNP) | VAF 219/511 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TSPAN2 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 142/305 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTF1 | c.1412A>G p.D471G | Missense Mutation (SNP) | VAF 171/399 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- TTN | c.24561G>A p.M8187I (on ENST00000591111; = p.M7260I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 161/385 reads (42%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- VEPH1 | c.425A>T p.K142M | Missense Mutation (SNP) | VAF 130/381 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- VLDLR | c.5G>C p.G2A | Missense Mutation (SNP) | VAF 135/229 reads (59%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- VPS13A | c.6818C>T p.S2273L | Missense Mutation (SNP) | VAF 105/245 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- VWA2 | c.1186C>A p.P396T | Missense Mutation (SNP) | VAF 193/315 reads (61%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- WDR97 | c.1635C>G p.I545M | Missense Mutation (SNP) | VAF 212/515 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WIZ | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 138/344 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- WTIP | c.840C>T p.Y280= | Splice Region (SNP) | VAF 146/352 reads (41%) | called by muse, mutect2, varscan2
- ZFP2 | c.472T>C p.Y158H | Missense Mutation (SNP) | VAF 182/422 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF106 | c.4769A>G p.Y1590C | Missense Mutation (SNP) | VAF 161/378 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF285 | c.226A>T p.I76F | Missense Mutation (SNP) | VAF 190/456 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ZNF729 | c.1166C>T p.S389L | Missense Mutation (SNP) | VAF 141/387 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF850 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 182/427 reads (43%) | called by muse, mutect2, varscan2
- ZNF90 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCB4 | c.3117C>T p.V1039= | Silent (SNP) | VAF 147/311 reads (47%) | catalogued as rs779194886, COSV55932665; called by muse, mutect2, varscan2
- ACKR2 | c.477C>T p.A159= | Silent (SNP) | VAF 154/377 reads (41%) | called by muse, mutect2, varscan2
- ANAPC1 | c.1305C>T p.D435= | Silent (SNP) | VAF 98/298 reads (33%) | called by muse, mutect2, varscan2
- ANKRD13C | c.369G>A p.G123= | Silent (SNP) | VAF 23/433 reads (5%) | catalogued as rs555091493; called by muse, mutect2
- APOBEC3A | c.250T>C p.L84= | Silent (SNP) | VAF 137/434 reads (32%) | catalogued as rs766912767; called by muse, mutect2, varscan2
- ARID4B | c.2037A>G p.V679= | Silent (SNP) | VAF 179/394 reads (45%) | catalogued as rs746537514; called by muse, mutect2, varscan2
- B4GALNT2 | c.867G>A p.L289= | Silent (SNP) | VAF 133/159 reads (84%) | called by muse, mutect2, varscan2
- CA12 | c.894A>T p.A298= | Silent (SNP) | VAF 28/444 reads (6%) | called by muse, mutect2
- CCDC85A | c.1065G>A p.R355= | Silent (SNP) | VAF 251/537 reads (47%) | called by muse, mutect2, varscan2
- COL1A2 | c.2346C>T p.P782= | Silent (SNP) | VAF 167/340 reads (49%) | called by muse, mutect2, varscan2
- COL9A1 | c.339C>T p.F113= | Silent (SNP) | VAF 133/288 reads (46%) | called by muse, mutect2, varscan2
- CPED1 | c.2736C>T p.N912= | Silent (SNP) | VAF 78/197 reads (40%) | called by muse, mutect2, varscan2
- CSF2RA | c.183C>T p.F61= | Silent (SNP) | VAF 202/225 reads (90%) | catalogued as COSV100817908; called by muse, mutect2, varscan2
- DCDC1 | c.2079G>A p.S693= | Silent (SNP) | VAF 160/372 reads (43%) | catalogued as rs267602843, COSV60854923; called by muse, varscan2
- DDN | c.1650G>A p.G550= | Silent (SNP) | VAF 32/590 reads (5%) | catalogued as rs1332366499; called by muse, mutect2
- DNAH2 | c.10638G>A p.R3546= | Silent (SNP) | VAF 113/134 reads (84%) | catalogued as rs1433345792; called by muse, mutect2, varscan2
- DOCK9 | c.1677T>C p.D559= (on ENST00000376460 / NM_001366676.2; = p.D560= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/459 reads (5%) | catalogued as rs1566897016; called by muse, mutect2
- DOHH | c.519C>T p.F173= | Silent (SNP) | VAF 239/568 reads (42%) | called by muse, mutect2, varscan2
- DSCAM | c.5895G>C p.P1965= | Silent (SNP) | VAF 221/250 reads (88%) | catalogued as COSV68031058; called by muse, mutect2, varscan2
- ERVMER34-1 | c.90A>T p.P30= | Silent (SNP) | VAF 176/350 reads (50%) | called by muse, mutect2, varscan2
- ESS2 | c.1239C>T p.A413= | Silent (SNP) | VAF 265/557 reads (48%) | called by muse, mutect2, varscan2
- FAM166B | c.225G>A p.E75= | Silent (SNP) | VAF 193/448 reads (43%) | called by muse, mutect2, varscan2
- FBXO4 | c.198A>G p.V66= | Silent (SNP) | VAF 106/204 reads (52%) | catalogued as rs761209346; called by muse, mutect2, varscan2
- FBXW8 | c.276C>T p.A92= | Silent (SNP) | VAF 194/233 reads (83%) | catalogued as rs1178583715; called by muse, mutect2, varscan2
- FRAS1 | c.7017T>C p.D2339= | Silent (SNP) | VAF 297/326 reads (91%) | called by muse, mutect2, varscan2
- FREM1 | c.2838G>A p.V946= | Silent (SNP) | VAF 195/231 reads (84%) | catalogued as COSV66528924; called by muse, mutect2, varscan2
- FRMD3 | c.858C>T p.F286= | Silent (SNP) | VAF 138/291 reads (47%) | catalogued as rs765258839; called by muse, mutect2, varscan2
- GALNT6 | c.1554G>A p.G518= | Silent (SNP) | VAF 96/329 reads (29%) | called by muse, mutect2, varscan2
- GCN1 | c.4587T>C p.P1529= | Silent (SNP) | VAF 155/191 reads (81%) | called by muse, mutect2, varscan2
- GPI | c.1143G>A p.G381= | Silent (SNP) | VAF 22/462 reads (5%) | catalogued as rs1214297048, COSV62894256; called by muse, mutect2
- GPR137 | c.1125C>T p.P375= | Silent (SNP) | VAF 207/458 reads (45%) | called by muse, mutect2, varscan2
- GPR139 | c.309C>T p.I103= | Silent (SNP) | VAF 178/357 reads (50%) | catalogued as rs1181418161, COSV58504322; called by muse, mutect2, varscan2
- HHAT | c.102G>A p.E34= | Silent (SNP) | VAF 143/345 reads (41%) | called by muse, mutect2, varscan2
- JADE1 | c.267C>T p.S89= | Silent (SNP) | VAF 160/344 reads (47%) | called by muse, mutect2, varscan2
- KCNJ5 | c.927G>A p.V309= | Silent (SNP) | VAF 110/314 reads (35%) | called by muse, mutect2, varscan2
- LDOC1 | c.312G>A p.V104= | Silent (SNP) | VAF 24/386 reads (6%) | called by muse, mutect2
- LHFPL2 | c.267C>T p.F89= | Silent (SNP) | VAF 294/613 reads (48%) | catalogued as rs369019734; called by muse, mutect2, varscan2
- LPAR4 | c.753C>T p.I251= | Silent (SNP) | VAF 224/267 reads (84%) | catalogued as COSV101425150; called by muse, mutect2, varscan2
- LRRN2 | c.1224C>T p.V408= | Silent (SNP) | VAF 226/504 reads (45%) | catalogued as COSV100912814; called by muse, mutect2, varscan2
- MAGEL2 | c.1362C>T p.A454= | Silent (SNP) | VAF 393/769 reads (51%) | called by muse, mutect2, varscan2
- MAML1 | c.2079T>C p.A693= | Silent (SNP) | VAF 152/324 reads (47%) | called by muse, mutect2, varscan2
- MAPK8IP3 | c.3906C>T p.D1302= | Silent (SNP) | VAF 78/248 reads (31%) | catalogued as rs762661117; called by muse, mutect2, varscan2
- MAPKAPK2 | c.636G>A p.K212= | Silent (SNP) | VAF 14/530 reads (3%) | called by muse, mutect2
- MDM1 | c.774T>C p.N258= | Silent (SNP) | VAF 22/306 reads (7%) | called by muse, mutect2
- MRPS15 | c.360G>A p.E120= | Silent (SNP) | VAF 14/384 reads (4%) | called by muse, mutect2
- MXRA5 | c.3693G>A p.R1231= | Silent (SNP) | VAF 280/329 reads (85%) | catalogued as rs761573472, COSV54248310; called by muse, mutect2, varscan2
- MYH2 | c.471C>T p.S157= | Silent (SNP) | VAF 178/207 reads (86%) | catalogued as rs149579742, COSV55433178; called by muse, mutect2, varscan2
- NEB | c.9153C>A p.A3051= | Silent (SNP) | VAF 181/441 reads (41%) | called by muse, mutect2, varscan2
- NLRP2 | c.855C>T p.F285= | Silent (SNP) | VAF 214/465 reads (46%) | catalogued as rs147098165, COSV54758751; called by muse, mutect2, varscan2
- NR3C2 | c.210A>G p.L70= | Silent (SNP) | VAF 198/387 reads (51%) | called by muse, mutect2, varscan2
- OR1L1 | c.426C>T p.I142= (on ENST00000373686; = p.I92= on NM_001005236.3) | Silent (SNP) | VAF 178/378 reads (47%) | called by muse, mutect2, varscan2
- OR7E24 | c.397C>T p.L133= | Silent (SNP) | VAF 124/293 reads (42%) | called by muse, mutect2, varscan2
- OR8B2 | c.795A>G p.G265= | Silent (SNP) | VAF 118/310 reads (38%) | catalogued as COSV66665577; called by muse, mutect2, varscan2
- PI4K2B | c.720G>T p.V240= | Silent (SNP) | VAF 113/267 reads (42%) | called by muse, mutect2, varscan2
- PRAMEF11 | c.225T>A p.P75= | Silent (SNP) | VAF 31/514 reads (6%) | catalogued as COSV101463197; called by muse, mutect2
- PRDM9 | c.2046C>T p.H682= | Silent (SNP) | VAF 220/578 reads (38%) | catalogued as COSV99691611; called by muse, mutect2, varscan2
- PRSS58 | c.192G>A p.V64= | Silent (SNP) | VAF 133/305 reads (44%) | catalogued as COSV73488882; called by muse, mutect2, varscan2
- PTPRT | c.2757G>A p.G919= | Silent (SNP) | VAF 241/258 reads (93%) | catalogued as rs569160745, COSV61967890; called by muse, mutect2, varscan2
- RAET1G | c.585G>A p.E195= | Silent (SNP) | VAF 261/390 reads (67%) | catalogued as rs760590294; called by muse, mutect2, varscan2
- RUSC2 | c.4128C>T p.A1376= | Silent (SNP) | VAF 202/476 reads (42%) | catalogued as COSV63428494, COSV63430217; called by muse, mutect2, varscan2
- SCN11A | c.3168C>T p.S1056= | Silent (SNP) | VAF 203/432 reads (47%) | catalogued as rs1484796137; called by muse, mutect2, varscan2
- SHBG | c.249G>A p.V83= | Silent (SNP) | VAF 151/175 reads (86%) | called by muse, mutect2, varscan2
- SLC26A1 | c.1569G>A p.E523= | Silent (SNP) | VAF 310/702 reads (44%) | called by muse, mutect2, varscan2
- SLC6A3 | c.627G>A p.G209= | Silent (SNP) | VAF 201/440 reads (46%) | catalogued as rs200564347; called by muse, mutect2, varscan2
- SMG7 | c.327G>A p.L109= | Silent (SNP) | VAF 86/212 reads (41%) | called by muse, mutect2, varscan2
- SMTNL1 | c.723C>T p.S241= (on ENST00000399154; = p.S278= on NM_001105565.2) | Silent (SNP) | VAF 231/494 reads (47%) | called by muse, mutect2, varscan2
- SUSD4 | c.1398G>A p.T466= | Silent (SNP) | VAF 192/431 reads (45%) | catalogued as rs762315284; called by muse, mutect2, varscan2
- TAS2R1 | c.105G>A p.L35= | Silent (SNP) | VAF 155/337 reads (46%) | catalogued as COSV66778962; called by muse, mutect2, varscan2
- TBC1D1 | c.3099T>A p.L1033= | Silent (SNP) | VAF 95/328 reads (29%) | called by muse, mutect2, varscan2
- TMEM41A | c.237C>T p.Y79= | Silent (SNP) | VAF 128/371 reads (35%) | catalogued as rs752986723; called by muse, mutect2, varscan2
- TTN | c.8604C>T p.V2868= (on ENST00000591111; = p.V2822= on NM_003319.4) | Silent (SNP) | VAF 148/338 reads (44%) | catalogued as rs753733308, COSV60176747; called by muse, mutect2, varscan2
- TULP3 | c.624G>A p.R208= | Silent (SNP) | VAF 209/447 reads (47%) | called by muse, mutect2, varscan2
- UNC79 | c.2715C>T p.I905= (on ENST00000393151 / NM_001346218.2; = p.I728= on NM_020818.5) | Silent (SNP) | VAF 191/451 reads (42%) | called by muse, mutect2, varscan2
- WDR87 | c.5862G>A p.L1954= | Silent (SNP) | VAF 26/350 reads (7%) | called by muse, mutect2
- ZFYVE28 | c.1977G>A p.Q659= | Silent (SNP) | VAF 40/594 reads (7%) | called by muse, mutect2
- ZNF429 | c.1281T>C p.C427= | Silent (SNP) | VAF 74/391 reads (19%) | called by muse, mutect2, varscan2
- ZNF761 | c.1011G>A p.Q337= | Silent (SNP) | VAF 188/401 reads (47%) | called by muse, mutect2, varscan2
- ZNF90 | c.222C>T p.S74= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as rs369463259; called by muse, mutect2, varscan2
- ZNFX1 | c.681G>A p.G227= | Silent (SNP) | VAF 328/359 reads (91%) | catalogued as rs374654504; called by muse, mutect2, varscan2
- AGAP13P | n.355C>T | RNA (SNP) | VAF 50/158 reads (32%) | called by muse, mutect2, varscan2
- DNAH14 | c.3052-22851T>A | Intron (SNP) | VAF 155/351 reads (44%) | called by muse, mutect2, varscan2
- GPNMB | c.541+26T>G | Intron (SNP) | VAF 214/455 reads (47%) | catalogued as rs766943234; called by muse, mutect2, varscan2
- GRIK5 | c.2514+1118C>T | Intron (SNP) | VAF 202/522 reads (39%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+16588G>A | Intron (SNP) | VAF 120/278 reads (43%) | called by muse, mutect2, varscan2
- KIAA1958 | c.1172-27358G>A | Intron (SNP) | VAF 187/217 reads (86%) | called by muse, mutect2, varscan2
- SNORD52 | chr6:31837424 T>C | 3'Flank (SNP) | VAF 181/426 reads (42%) | called by muse, mutect2, varscan2
- TAL1 | c.*2175G>T | 3'UTR (SNP) | VAF 20/286 reads (7%) | called by muse, mutect2
- TASOR2 | c.-262A>T | 5'UTR (SNP) | VAF 80/202 reads (40%) | called by muse, mutect2, varscan2
- TMEM8B | c.-497T>C | 5'UTR (SNP) | VAF 168/388 reads (43%) | called by muse, mutect2, varscan2
- TTN | c.34265-3019G>A | Intron (SNP) | VAF 74/330 reads (22%) | called by muse, mutect2, varscan2
- UBR4 | c.15009-31C>T | Intron (SNP) | VAF 34/536 reads (6%) | called by muse, mutect2
- ZNF264 | c.160+846A>G | Intron (SNP) | VAF 89/299 reads (30%) | called by muse, mutect2, varscan2
- ZNF829 | c.320-502C>T | Intron (SNP) | VAF 85/276 reads (31%) | called by muse, mutect2, varscan2
